Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A2I4, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A2I4-01A (Primary Tumor).

[page 1 of 5]
PATHOLOGY REPORT

Reformatted Report

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Location:

Service: Urology

Billing

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Type:

Additional Copy to:

Other Related Data:

Billing Type:

INPATIENT

Financial Number:

Clinical Diagnosis & History:

male with h/o muscle invasive TCC bladder.

ICD-0-3

carcinoma, papillary urothelial
(transitional cell) 8130/3

Site: bladder, wall, anterior C67-3

for
6/24/11

Specimens Submitted:

- 1: SP: Rt. ureter
- 2: SP: Lt. ureter
- 3: SP: Bladder, prostate & seminal vesicles
- 4: SP: Right vas deferens
- 5: SP: Left vas deferens
- 6: SP: Right pelvic lymph nodes
- 7: SP: Right common iliac lymph nodes
- 8: SP: Left pelvic lymph nodes
- 9: SP: Left common iliac lymph nodes

DIAGNOSIS:

- 1) URETER, RIGHT; BIOPSY:
- BENIGN URETER.
- 2) URETER, LEFT; BIOPSY:
- BENIGN URETER.
- 3) BLADDER, PROSTATE AND SEMINAL VESICLES; RESECTION:
- TRANSITIONAL CELL CARCINOMA, POORLY DIFFERENTIATED. THE PATTERN OF GROWTH IS PAPILLARY AND FLAT. THE TUMOR INVADES INTO THE PERIVESICAL SOFT TISSUES (pT3b). THE TUMOR DOES NOT EXTEND BEYOND THE BLADDER. NO VASCULAR INVASION IS IDENTIFIED. NO PERINEURAL INVASION IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC MUCOSA SHOWS THE FOLLOWING ABNORMALITY(IES): GRANULOMATOUS CYSTITIS. THE PROSTATE SHOWS PROSTATITIS. THE SEMINAL VESICLES ARE UNREMARKABLE.
- 4) VAS DEFERENS, RIGHT; RESECTION:
- BENIGN VAS DEFERENS.
- 5) VAS DEFERENS, LEFT; RESECTION:
- BENIGN VAS DEFERENS.
- 6) LYMPH NODES, RIGHT PELVIC; BIOPSY:
- FIVE BENIGN LYMPH NODES (0/5).

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

- 7) LYMPH NODES, RIGHT COMMON ILIAC; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH SCATTERED BENIGN LYMPHOID AGGREGATES.
- 8) LYMPH NODES, LEFT PELVIC; BIOPSY:
- EIGHT BENIGN LYMPH NODES (0/8).
- 9) LYMPH NODE, LEFT COMMON ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled "Right ureter". It consists of a tan, rubbery, tubular fragment measuring 0.3 cm in diameter. The entire specimen is submitted for frozen section diagnosis in one cassette.

Summary of sections:
FSC - frozen section control

2) The specimen is received fresh for frozen section diagnosis, labeled "Left ureter". It consists of portion of tubular shaped tissue measuring 0.4 x 0.4 x 0.2 cm. The entire specimen is submitted for frozen section diagnosis in one cassette.

Summary of sections:
FSC - frozen section control

3) The specimen is received fresh for frozen section, labeled "Bladder, Prostate and Seminal Vesicles". It consists of a fragment of tissue measuring 19 x 12 x 2.5 cm. The prostate and bladder are easily recognizable. The prostate is separated from the bladder and submitted as whole mount sections. Upon opening, the bladder cavity is partly ulcerated, partly edematous, especially on the anterior wall. There is a papillary lesion located at the superior part of the anterior wall, close to the dome. The ulcerated area comes close to the bladder neck, where the prostate begins. Some tissue is saved for TPS and pictures are taken. The specimen is sampled in a total of fourteen cassettes.

The specimen also consists of a radical prostatectomy specimen which includes prostate, seminal vesicles, and portions of right and left vasa deferentia. The specimen weighs 35 grams. The

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

prostate measures 2.3 cm from apex to base, 4.5 cm transversely and 4.2 cm from anterior to posterior. The right seminal vesicle measures 3 x 0.6 x 0.6 cm and the left seminal vesicle measures 3.1 x 0.6 x 0.6 cm. The external surface of the prostate is smooth. The prostate is serially sectioned from apex to base at approximately 3 mm intervals. 100% of the prostatic tissue is submitted.

Summary of Sections:

LUM - left ureteral margin
RUM - right ureteral margin
LUO - left ureteral orifice
RUO - right ureteral orifice
DOVE - lesion near the dome
T - tumor area on anterior bladder wall
BNEF - bladder neck en face
PW - posterior wall

4) The specimen is received in formalin, labeled "Right Vas Deferens". It consists of a tubular structure measuring 4.5 cm in length and 0.3 cm in diameter. Representative sections are submitted in one block.

Summary of Sections:

U - undesignated

5) The specimen is received in formalin, labeled "Left Vas Deferens". It consists of a tubular structure measuring 5 cm in length and 0.3 cm in diameter. Representative sections are submitted in one block.

Summary of Sections:

U - undesignated

6) The specimen is received in formalin, labeled "Right Pelvic Lymph Nodes". It consists of an aggregate of fibrofatty soft tissue measuring 6 x 4.5 x 3 cm approximately. Possible lymph nodes are submitted in four cassettes.

Summary of Sections:

U - undesignated

7) The specimen is received in formalin, labeled "Right Common Iliac Lymph Nodes". It consists of a fragment of fibrofatty soft tissue measuring 2 x 1 x 1 cm. The specimen is entirely submitted in one cassette.

Summary of Sections:

U - undesignated

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

8) The specimen is received in formalin, labeled "Left Pelvic Lymph Nodes". It consists of several fragments of fibrofatty soft tissue forming an aggregate measuring 7.5 x 3 x 2.5 cm. Possible lymph nodes are submitted in four cassettes.

Summary of Sections:

U - undesignated

9) The specimen is received in formalin, labeled "Left Common Iliac Lymph Nodes". It consists of a fragment of fibrofatty soft tissue measuring 1.5 x 1 x 1 cm. The specimen is bisected and entirely submitted in one cassette.

Summary of Sections:

U - undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	1	Y
2	FSC		1	1	Y
3	A		1	1	N
	B		1	1	
	BN		1	M	
	C		1	1	
	D		1	1	
	E		1	1	
	F		1	1	
	G		1	1	
	LA		1	M	
	LSV		1	M	
	RA		1	M	
	RSV		1	M	
	bnf		2	M	
	dome		2	M	
	lum		1	1	
	luo		1	1	
	pw		1	1	
	rum		1	1	
	ruo		1	1	
	t		5	M	
4	u		1	M	N
5	u		1	M	N
6	u		4	M	N
7	u		1	M	Y
8	u		4	M	N
9	u		1	M	Y

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file 00a45f17-b182-45f4-92f4-4bf406a66323 (TCGA-DK-A2I4.C521242F-494B-4399-AF73-302A96F3BC48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).